CCDI case PBCBJZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/67456106-e8b1-41d7-9d8c-3127b5ac019a

Demographics
Sex at birth: female; Race: american indian or alaska native.

Diagnoses (1)
1. Sertoli-Leydig cell tumor, intermediate differentiation, with heterologous elements: ICD-O-3 morphology code: 8634/1; Tissue or organ of origin: Ovary; Age at diagnosis: 17.5 years (6,392 days).

Biospecimens (3 samples)
- Sample 0DNCAG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNCH4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNCOL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
